Somatic mutation profile of tumor specimen C3L-03378-04 (aliquot CPT0199880006) from CPTAC case C3L-03378, project CPTAC-3 (Other and ill-defined sites in lip, oral cavity and pharynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 54.8 years (20,019 days).
Specimen C3L-03378-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oral Cavity; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 619597eb-c138-43aa-bad6-6db05165f147.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03378-31 (Blood Derived Normal), aliquot CPT0200430002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/036fe77d-bf81-46fb-b491-c66320c36626

The open-access MAF lists 253 somatic variants for this specimen: 170 protein-altering or splice-affecting, 54 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 54, Nonsense Mutation 16, Intron 16, Splice Site 6, 5'UTR 6, RNA 4, Frame Shift Ins 4, Splice Region 3, 3'UTR 2, In Frame Del 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 360/660 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP63 | c.580-1G>T p.X194_splice | Splice Site (SNP) | VAF 22/476 reads (5%) | hotspot (GDC flag); catalogued as COSV53205039, COSV99285668; called by muse, mutect2
- ABCG8 | c.670G>T p.G224W | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55395472; called by muse, mutect2, varscan2
- AC004890.2 | n.1486G>A | Splice Region (SNP) | VAF 33/212 reads (16%) | catalogued as rs1046554666; called by muse, mutect2, varscan2
- ADAM22 | c.1157A>T p.K386M | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV55974806; called by muse, mutect2
- ADAMTS12 | c.2894G>A p.R965Q | Missense Mutation (SNP) | VAF 51/516 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.28); catalogued as rs563669246, COSV100711796, COSV61255980; called by muse, mutect2
- ANKRD18A | c.1372dup p.M458Nfs*4 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | catalogued as rs1392211316; called by mutect2, pindel, varscan2
- APLF | c.249G>C p.L83F | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100376455; called by muse, mutect2
- BAHCC1 | c.6824C>T p.P2275L | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.55); catalogued as COSV100312148; called by muse, mutect2, varscan2
- BMS1 | c.3685C>T p.R1229W | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs758830109; called by muse, mutect2, varscan2
- CHML | c.583G>C p.D195H | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.667); catalogued as COSV100087610; called by muse, mutect2
- CHRD | c.2482G>A p.V828M | Missense Mutation (SNP) | VAF 122/458 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1481968249; called by muse, mutect2, varscan2
- COX5B | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.353); catalogued as rs760321949, COSV51480877; called by muse, mutect2, varscan2
- DISP1 | c.2471A>G p.Q824R | Missense Mutation (SNP) | VAF 48/552 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763588849; called by muse, mutect2
- DNAH6 | c.2041G>T p.E681* | Nonsense Mutation (SNP) | VAF 17/152 reads (11%) | catalogued as COSV52868108; called by muse, mutect2, varscan2
- DNAJC13 | c.4904G>A p.S1635N | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.878); catalogued as rs1216491078; called by muse, mutect2, varscan2
- EEA1 | c.1746G>C p.E582D | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.97); catalogued as COSV59282766; called by muse, mutect2, varscan2
- FAM47A | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs758963950, COSV60494403; called by muse, mutect2, varscan2
- FGF17 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV63925697; called by muse, mutect2, varscan2
- FKBP6 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 193/612 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782776540, COSV52723525; called by muse, mutect2, varscan2
- GADD45A | c.200G>C p.R67T | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.12); catalogued as rs1029899218; called by muse, mutect2, varscan2
- GALC | c.1916A>T p.H639L | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs781113050; called by muse, varscan2
- GCC2 | c.3091G>A p.E1031K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV59180292; called by muse, mutect2, varscan2
- GTPBP2 | c.1594G>A p.V532I | Missense Mutation (SNP) | VAF 117/446 reads (26%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.688); catalogued as rs756635042; called by mutect2, varscan2
- H2BC8 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs973582647; called by muse, varscan2
- HNMT | c.464T>G p.L155R | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV54508192; called by muse, mutect2
- ICE1 | c.5545C>T p.R1849C | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs753732735, COSV56822229; called by muse, mutect2, varscan2
- ITGA4 | c.323G>A p.S108N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs189570672; called by muse, varscan2
- ITSN1 | c.4504G>A p.D1502N | Missense Mutation (SNP) | VAF 110/286 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773094165, COSV67157597; called by muse, mutect2, varscan2
- KANK1 | c.334C>G p.Q112E | Missense Mutation (SNP) | VAF 39/332 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as COSV63213262; called by muse, mutect2, varscan2
- LRRTM1 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 52/252 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54439946; called by muse, mutect2, varscan2
- MDGA2 | c.1648G>T p.D550Y (on ENST00000399232 / NM_001113498.2; = p.D252Y on NM_182830.4) | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62121853; called by muse, mutect2, varscan2
- MPP4 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59634473; called by muse, varscan2
- MTRR | c.548C>G p.S183* (on ENST00000264668; = p.S156* on NM_002454.3 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/179 reads (11%) | catalogued as rs919772858; called by muse, mutect2, varscan2
- MYDGF | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs765668010; called by muse, mutect2, varscan2
- NOTCH3 | c.5282G>A p.R1761H | Missense Mutation (SNP) | VAF 25/246 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs747749554, COSV54638173; called by muse, mutect2, varscan2
- NUP107 | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 35/150 reads (23%) | catalogued as COSV57494534; called by muse, mutect2, varscan2
- OR10W1 | c.751C>A p.L251M | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV67720900; called by muse, mutect2, varscan2
- OR4K15 | c.496G>A p.V166I (on ENST00000305051; = p.V142I on NM_001005486.1) | Missense Mutation (SNP) | VAF 33/264 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766826567; called by muse, mutect2, varscan2
- OR6C70 | c.304dup p.Y102Lfs*18 | Frame Shift Ins (INS) | VAF 30/133 reads (23%) | catalogued as rs750079585; called by mutect2, varscan2
- PCDHA11 | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 128/373 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs374687707, COSV56514685; called by muse, mutect2, varscan2
- PDE1C | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 55/259 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100372838, COSV58523494; called by muse, mutect2, varscan2
- PECR | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747109771, COSV54735056, COSV54735128; called by muse, mutect2, varscan2
- PLEKHG1 | c.223G>T p.G75W | Missense Mutation (SNP) | VAF 98/197 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV62044768; called by muse, mutect2, varscan2
- PLXNA4 | c.4438G>A p.E1480K | Missense Mutation (SNP) | VAF 47/385 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs774839624, COSV58118492; called by muse, mutect2, varscan2
- POMT1 | c.994G>A p.V332I | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs190112934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPFIA3 | c.2463-1G>A p.X821_splice | Splice Site (SNP) | VAF 49/184 reads (27%) | catalogued as COSV61951462; called by muse, mutect2, varscan2
- PPM1A | c.1120-2A>G p.X374_splice | Splice Site (SNP) | VAF 18/66 reads (27%) | catalogued as COSV57786888; called by muse, mutect2, varscan2
- RTCA | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs1001603550, COSV53120052; called by muse, mutect2, varscan2
- SCN10A | c.2306C>A p.S769Y | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV71861126; called by muse, mutect2, varscan2
- SIRPG | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 129/463 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.901); catalogued as rs375274090; called by muse, mutect2, varscan2
- SKIDA1 | c.974G>C p.R325T | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs1329179995; called by muse, varscan2
- SMARCAD1 | c.2303dup p.N768Kfs*28 | Frame Shift Ins (INS) | VAF 10/97 reads (10%) | catalogued as rs750056186; called by mutect2, varscan2
- STAT1 | c.1942A>G p.I648V | Missense Mutation (SNP) | VAF 68/316 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs369876674; called by muse, mutect2, varscan2
- SUSD2 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV54077934; called by muse, mutect2, varscan2
- TBC1D10C | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs764633775; called by muse, mutect2, varscan2
- THNSL1 | c.461T>C p.L154P | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs35827877; called by muse, mutect2, varscan2
- TMEM128 | c.220G>A p.E74K (on ENST00000382753 / NM_001297552.2; = p.E50K on NM_032927.3) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV54636524; called by muse, varscan2
- VIPAS39 | c.735-5C>T | Splice Region (SNP) | VAF 112/412 reads (27%) | catalogued as COSV58938525; called by muse, mutect2, varscan2
- VPS13A | c.5614G>A p.V1872I | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs979019015; called by muse, mutect2, varscan2
- XYLB | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 102/309 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52911884; called by muse, mutect2, varscan2
- ZBTB41 | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV66360191; called by muse, mutect2, varscan2
- ZNF318 | c.4363C>T p.P1455S | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.23); catalogued as COSV58931465; called by muse, mutect2, varscan2
- ZNF616 | c.2240G>T p.C747F | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1309161702; called by muse, mutect2, varscan2
- ZNF676 | c.1418G>T p.R473I (on ENST00000650058; = p.R441I on NM_001001411.3) | Missense Mutation (SNP) | VAF 124/456 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.254); catalogued as rs764369632, COSV101236165, COSV68092102, COSV68092115; called by muse, varscan2
- ZNF841 | c.1938G>C p.E646D (on ENST00000426391 / NM_001369830.1; = p.E762D on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV100744822; called by muse, mutect2, varscan2
- ACAT2 | c.473G>T p.C158F | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2
- ACTRT3 | c.735C>G p.I245M | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2
- ADAMTS5 | c.2292A>C p.K764N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AGRN | c.5537G>C p.G1846A | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHCY | c.983A>G p.Y328C | Missense Mutation (SNP) | VAF 129/475 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4925C>T p.S1642F | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- ATP4A | c.2851C>A p.R951S | Missense Mutation (SNP) | VAF 114/387 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- BLVRA | c.374A>G p.H125R | Missense Mutation (SNP) | VAF 50/458 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CASZ1 | c.717T>G p.Y239* | Nonsense Mutation (SNP) | VAF 68/322 reads (21%) | called by muse, mutect2, varscan2
- CCAR1 | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 58/253 reads (23%) | called by muse, mutect2, varscan2
- CCDC168 | c.5966dup p.N1989Kfs*14 | Frame Shift Ins (INS) | VAF 25/82 reads (30%) | called by mutect2, pindel, varscan2
- CHST10 | c.257A>T p.E86V | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- CNST | c.1616A>G p.Q539R | Missense Mutation (SNP) | VAF 69/383 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL22A1 | c.2791G>C p.G931R | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- COPB2 | c.2503G>A p.V835I | Missense Mutation (SNP) | VAF 11/262 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- CSMD3 | c.8137T>C p.S2713P | Missense Mutation (SNP) | VAF 45/256 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTNNA2 | c.2296-1G>T p.X766_splice | Splice Site (SNP) | VAF 6/37 reads (16%) | called by muse, varscan2
- CYB5A | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 61/502 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- CYP11B1 | c.1160G>A p.S387N | Missense Mutation (SNP) | VAF 173/609 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DCAF11 | c.1433A>C p.K478T | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- DCAF5 | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 45/299 reads (15%) | called by muse, mutect2, varscan2
- DDC | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 72/455 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DGCR2 | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- DLGAP4 | c.2075G>C p.G692A (on ENST00000339266 / NM_001365621.1; = p.G153A on NM_183006.4) | Missense Mutation (SNP) | VAF 35/391 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2
- DTL | c.2019G>C p.E673D | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DYRK4 | c.1061A>G p.K354R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- EHBP1 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 17/223 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ENTPD6 | c.1259A>G p.E420G | Missense Mutation (SNP) | VAF 25/323 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.056); called by muse, mutect2
- ERICH3 | c.2873C>T p.P958L | Missense Mutation (SNP) | VAF 106/244 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- EXD3 | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 83/544 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- FAM200A | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- FOXM1 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
- FRYL | c.1514C>G p.S505* | Nonsense Mutation (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- GAS2L3 | c.320A>T p.K107I | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- GATA4 | c.1146+1G>A p.X382_splice | Splice Site (SNP) | VAF 27/171 reads (16%) | called by muse, mutect2, varscan2
- GCLC | c.886G>A p.D296N (on ENST00000643939; = p.D294N on NM_001498.4) | Missense Mutation (SNP) | VAF 109/565 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GFPT1 | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GTPBP8 | c.307G>C p.D103H | Missense Mutation (SNP) | VAF 30/457 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); called by muse, mutect2
- HAS1 | c.1208_1222del p.Y403_V407del | In Frame Del (DEL) | VAF 70/613 reads (11%) | called by mutect2, pindel
- HDAC9 | c.2668G>A p.A890T | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HMBOX1 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HMCN2 | c.15150G>C p.L5050F | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- HSD17B7P2 | n.724G>T | Splice Region (SNP) | VAF 19/133 reads (14%) | called by muse, mutect2, varscan2
- IFT122 | c.3225C>G p.I1075M (on ENST00000348417 / NM_052989.3; = p.I1016M on NM_018262.4) | Missense Mutation (SNP) | VAF 27/840 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.278); called by muse, mutect2
- IGHV3-43 | c.338A>T p.Y113F | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2
- IGSF3 | c.527A>G p.H176R | Missense Mutation (SNP) | VAF 125/337 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INSRR | c.1616G>A p.G539E | Missense Mutation (SNP) | VAF 14/488 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNH2 | c.946C>T p.L316F | Missense Mutation (SNP) | VAF 119/502 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- KIFBP | c.544G>C p.D182H | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- LARP7 | c.751A>C p.M251L | Missense Mutation (SNP) | VAF 106/231 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- LCT | c.321G>C p.E107D | Missense Mutation (SNP) | VAF 57/411 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRFN4 | c.702C>A p.N234K | Missense Mutation (SNP) | VAF 47/299 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LRP2 | c.2311G>C p.D771H | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, varscan2
- LRRC37A2 | c.2921A>T p.N974I | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- LRRK2 | c.4771C>T p.Q1591* | Nonsense Mutation (SNP) | VAF 74/345 reads (21%) | called by muse, mutect2, varscan2
- LUZP2 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- MACC1 | c.266A>G p.K89R | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2
- MAGEA3 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.674); called by muse, varscan2
- MAP2K1 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 153/513 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARCHF9 | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 69/280 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- MB21D2 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 44/581 reads (8%) | called by muse, mutect2
- MFAP3 | c.710G>A p.R237K | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- MFN2 | c.2244C>G p.F748L | Missense Mutation (SNP) | VAF 57/313 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MKLN1 | c.1941G>T p.K647N | Missense Mutation (SNP) | VAF 39/289 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MMGT1 | c.55C>G p.H19D | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYH6 | c.1001A>T p.D334V | Missense Mutation (SNP) | VAF 188/665 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- NEMP2 | c.977C>G p.S326* | Nonsense Mutation (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- NKTR | c.3492G>C p.Q1164H | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- NLRP7 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NMNAT3 | c.148A>G p.N50D (on ENST00000296202 / NM_001320512.1; = p.N13D on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.695); called by muse, mutect2
- OPTN | c.314A>G p.E105G | Missense Mutation (SNP) | VAF 82/361 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- OR13C9 | c.629C>A p.P210Q | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PAPPA2 | c.2689G>A p.A897T | Missense Mutation (SNP) | VAF 62/413 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PCNX1 | c.5585A>G p.H1862R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- PDE7B | c.1243_1260del p.S415_Q420del | In Frame Del (DEL) | VAF 161/500 reads (32%) | called by mutect2, pindel, varscan2
- PHF3 | c.4493T>A p.F1498Y | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- POLRMT | c.2985G>C p.M995I | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PPP2R5C | c.885G>C p.K295N | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRRX1 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 193/447 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- PUS7 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- RBMX2 | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 121/175 reads (69%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RETN | c.118+1G>A p.X40_splice | Splice Site (SNP) | VAF 48/368 reads (13%) | called by muse, mutect2, varscan2
- RFX7 | c.2999C>T p.P1000L (on ENST00000559447 / NM_001368074.1; = p.P1097L on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RGMA | c.48G>T p.W16C | Missense Mutation (SNP) | VAF 33/289 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ROBO3 | c.2852C>A p.P951H | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.707); called by muse, mutect2
- SEPTIN9 | c.778G>C p.G260R (on ENST00000427177 / NM_001113491.2; = p.G242R on NM_006640.4) | Missense Mutation (SNP) | VAF 24/267 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- SI | c.2875G>T p.G959C | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SKIDA1 | c.14A>G p.K5R | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- SNAPC2 | c.31C>G p.P11A | Missense Mutation (SNP) | VAF 173/457 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- SPINDOC | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 35/155 reads (23%) | called by muse, mutect2, varscan2
- TACR3 | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 160/389 reads (41%) | called by muse, mutect2, varscan2
- TDG | c.1046del p.N349Ifs*15 | Frame Shift Del (DEL) | VAF 20/164 reads (12%) | called by mutect2, varscan2
- TMPO | c.907A>T p.K303* | Nonsense Mutation (SNP) | VAF 31/221 reads (14%) | called by muse, mutect2, varscan2
- TRIM58 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBA3 | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- UBAC1 | c.278A>G p.K93R | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- UBE4A | c.1043A>T p.N348I (on ENST00000252108 / NM_001204077.2; = p.N355I on NM_004788.4) | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- VPS11 | c.1045G>C p.D349H (on ENST00000620429; = p.D893H on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- WIZ | c.557G>A p.W186* | Nonsense Mutation (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2
- XPO5 | c.356T>A p.I119N | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZNF205 | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF714 | c.687C>A p.Y229* | Nonsense Mutation (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- ZNF835 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 76/692 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF835 | c.18C>A p.S6R | Missense Mutation (SNP) | VAF 58/481 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- A2ML1 | c.2025C>T p.F675= | Silent (SNP) | VAF 25/122 reads (20%) | called by muse, mutect2, varscan2
- ABCA9 | c.4554G>A p.L1518= | Silent (SNP) | VAF 75/300 reads (25%) | called by muse, mutect2, varscan2
- ABCC8 | c.3027C>T p.I1009= | Silent (SNP) | VAF 53/377 reads (14%) | catalogued as rs751662850; called by muse, mutect2, varscan2
- ACTL9 | c.1113T>A p.A371= | Silent (SNP) | VAF 34/270 reads (13%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.537C>A p.A179= | Silent (SNP) | VAF 19/189 reads (10%) | called by muse, mutect2
- APC2 | c.3198G>A p.S1066= | Silent (SNP) | VAF 83/249 reads (33%) | catalogued as rs1192571326; called by muse, mutect2, varscan2
- ATP10A | c.3030G>A p.Q1010= | Silent (SNP) | VAF 25/148 reads (17%) | called by muse, mutect2, varscan2
- ATXN2 | c.2106C>T p.P702= (on ENST00000550104; = p.P542= on NM_002973.4) | Silent (SNP) | VAF 18/165 reads (11%) | catalogued as rs187372835; called by muse, mutect2
- BTNL9 | c.477C>G p.L159= | Silent (SNP) | VAF 27/139 reads (19%) | called by muse, mutect2, varscan2
- C1orf115 | c.123C>T p.Y41= | Silent (SNP) | VAF 95/194 reads (49%) | called by muse, mutect2, varscan2
- CASP14 | c.333C>T p.A111= | Silent (SNP) | VAF 33/202 reads (16%) | catalogued as COSV55666448; called by muse, mutect2, varscan2
- CATSPERB | c.684A>C p.T228= | Silent (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
- CCDC168 | c.3240A>T p.T1080= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs749709197; called by muse, mutect2, varscan2
- COG4 | c.1722C>T p.T574= | Silent (SNP) | VAF 84/424 reads (20%) | called by muse, mutect2, varscan2
- CSMD3 | c.1197G>T p.T399= | Silent (SNP) | VAF 27/366 reads (7%) | catalogued as COSV52156062; called by muse, mutect2
- DDX17 | c.465G>A p.K155= | Silent (SNP) | VAF 80/432 reads (19%) | called by muse, mutect2, varscan2
- DISC1 | c.324G>A p.V108= | Silent (SNP) | VAF 56/725 reads (8%) | catalogued as rs1291157621; called by muse, mutect2
- DLGAP4 | c.1683G>A p.P561= | Silent (SNP) | VAF 31/128 reads (24%) | catalogued as rs1452222455, COSV100211617; called by muse, varscan2
- ENKUR | c.693A>G p.E231= | Silent (SNP) | VAF 14/310 reads (5%) | called by muse, mutect2
- FAM135B | c.1197C>T p.D399= | Silent (SNP) | VAF 61/259 reads (24%) | catalogued as rs552788793, COSV52731909; called by muse, mutect2, varscan2
- FAM91A1 | c.567G>A p.E189= | Silent (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2, varscan2
- FANCG | c.571T>C p.L191= | Silent (SNP) | VAF 65/444 reads (15%) | called by muse, mutect2, varscan2
- FCGBP | c.1431C>T p.D477= | Silent (SNP) | VAF 86/331 reads (26%) | called by muse, mutect2, varscan2
- GALNS | c.495C>T p.C165= | Silent (SNP) | VAF 34/183 reads (19%) | called by muse, mutect2, varscan2
- GLB1L2 | c.387G>A p.L129= | Silent (SNP) | VAF 27/216 reads (13%) | catalogued as COSV60278323; called by muse, mutect2, varscan2
- GLS2 | c.720G>A p.K240= | Silent (SNP) | VAF 51/189 reads (27%) | catalogued as rs1292595965; called by muse, mutect2, varscan2
- H2BC21 | c.309G>C p.L103= | Silent (SNP) | VAF 78/970 reads (8%) | called by muse, mutect2
- HEG1 | c.2112T>A p.S704= | Silent (SNP) | VAF 255/422 reads (60%) | called by muse, mutect2, varscan2
- IGF2R | c.678G>A p.R226= | Silent (SNP) | VAF 116/318 reads (36%) | called by muse, mutect2, varscan2
- KCNK17 | c.924T>C p.Y308= | Silent (SNP) | VAF 148/305 reads (49%) | called by muse, mutect2, varscan2
- LILRB4 | c.753C>T p.H251= | Silent (SNP) | VAF 33/120 reads (28%) | catalogued as rs1178275804; called by muse, mutect2, varscan2
- LRP1 | c.3768T>A p.P1256= | Silent (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2
- MAP3K20 | c.6G>T p.S2= | Silent (SNP) | VAF 29/93 reads (31%) | called by muse, mutect2, varscan2
- MED13L | c.5034C>T p.V1678= | Silent (SNP) | VAF 55/389 reads (14%) | called by muse, mutect2, varscan2
- MUC16 | c.24531G>A p.E8177= | Silent (SNP) | VAF 24/206 reads (12%) | catalogued as rs770695416; called by muse, mutect2, varscan2
- OR2B6 | c.804G>A p.K268= | Silent (SNP) | VAF 19/164 reads (12%) | catalogued as COSV99773576; called by muse, mutect2, varscan2
- PIK3CB | c.2463C>G p.R821= | Silent (SNP) | VAF 42/192 reads (22%) | called by muse, mutect2, varscan2
- PKD2L1 | c.1272G>A p.T424= | Silent (SNP) | VAF 86/224 reads (38%) | catalogued as rs759705584; called by muse, mutect2, varscan2
- PKHD1 | c.11721C>T p.I3907= | Silent (SNP) | VAF 97/370 reads (26%) | catalogued as rs751898701; called by muse, mutect2, varscan2
- PTPRB | c.2007A>C p.G669= | Silent (SNP) | VAF 28/392 reads (7%) | called by muse, mutect2
- RLN1 | c.456C>T p.G152= | Silent (SNP) | VAF 19/189 reads (10%) | called by muse, mutect2, varscan2
- SCAP | c.3831G>A p.K1277= | Silent (SNP) | VAF 36/93 reads (39%) | called by muse, mutect2, varscan2
- SCIN | c.1491A>G p.G497= (on ENST00000297029 / NM_001112706.3; = p.G250= on NM_033128.3) | Silent (SNP) | VAF 21/245 reads (9%) | called by muse, mutect2
- SETD7 | c.981C>T p.A327= | Silent (SNP) | VAF 38/147 reads (26%) | catalogued as rs773482699, COSV56799603; called by muse, mutect2, varscan2
- SPRY3 | c.81C>T p.Y27= | Silent (SNP) | VAF 112/270 reads (41%) | catalogued as rs192786119, COSV57142441; called by muse, mutect2, varscan2
- SRSF7 | c.318C>T p.C106= | Silent (SNP) | VAF 23/88 reads (26%) | called by muse, mutect2, varscan2
- TCN1 | c.882G>T p.L294= | Silent (SNP) | VAF 29/155 reads (19%) | catalogued as COSV57253194; called by muse, mutect2, varscan2
- TMEM8B | c.750G>C p.V250= | Silent (SNP) | VAF 49/328 reads (15%) | catalogued as rs749036375; called by muse, mutect2, varscan2
- TPRN | c.723C>T p.S241= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- ZNF341 | c.1176G>A p.Q392= (on ENST00000375200 / NM_001282935.1; = p.Q385= on NM_032819.4) | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs764166660, COSV61005821; called by muse, mutect2, varscan2
- ZNF443 | c.1983C>A p.L661= | Silent (SNP) | VAF 20/179 reads (11%) | called by muse, varscan2
- ZNF816 | c.99C>T p.F33= | Silent (SNP) | VAF 24/256 reads (9%) | called by muse, mutect2
- ZNF821 | c.561C>T p.F187= (on ENST00000425432 / NM_001376297.1; = p.F145= on NM_017530.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 30/170 reads (18%) | catalogued as rs756400393; called by muse, mutect2, varscan2
- ZNF865 | c.3114G>A p.A1038= | Silent (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- ASIC4 | c.*47G>A | 3'UTR (SNP) | VAF 79/239 reads (33%) | called by muse, mutect2, varscan2
- C10orf105 | c.-10C>T | 5'UTR (SNP) | VAF 63/535 reads (12%) | called by muse, mutect2, varscan2
- CHST10 | c.-46C>G | 5'UTR (SNP) | VAF 18/246 reads (7%) | called by muse, mutect2
- COL6A4P1 | n.762G>A | RNA (SNP) | VAF 52/120 reads (43%) | called by muse, mutect2, varscan2
- DBF4B | c.1189+59G>A | Intron (SNP) | VAF 66/238 reads (28%) | called by muse, mutect2, varscan2
- EEPD1 | c.-1C>T | 5'UTR (SNP) | VAF 29/83 reads (35%) | catalogued as rs1186555876; called by muse, mutect2, varscan2
- FSHR | c.374+2566G>A | Intron (SNP) | VAF 16/184 reads (9%) | called by muse, mutect2
- GIMAP2 | c.28+2440A>G | Intron (SNP) | VAF 45/221 reads (20%) | called by muse, mutect2, varscan2
- ITSN1 | c.2728-697C>T | Intron (SNP) | VAF 18/73 reads (25%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.474A>T | RNA (SNP) | VAF 33/264 reads (13%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-11550C>A | Intron (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
- NCF1B | n.159-1523C>T | Intron (SNP) | VAF 66/1017 reads (6%) | called by muse, mutect2
- PCBP2 | c.1061+3390C>T | Intron (SNP) | VAF 24/98 reads (24%) | called by muse, mutect2, varscan2
- PCNX2 | c.3838-17100G>C | Intron (SNP) | VAF 15/251 reads (6%) | called by muse, mutect2
- PPP2CB | c.*209C>A | 3'UTR (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- PRB4 | c.-36C>T | 5'UTR (SNP) | VAF 120/574 reads (21%) | called by muse, mutect2, varscan2
- RELT | c.626-151C>T | Intron (SNP) | VAF 17/180 reads (9%) | called by muse, mutect2
- RFX5 | c.233+45G>C | Intron (SNP) | VAF 31/294 reads (11%) | called by muse, mutect2, varscan2
- SEBOX | c.-48C>T | 5'UTR (SNP) | VAF 37/162 reads (23%) | catalogued as rs1555582847; called by muse, mutect2, varscan2
- SIAH1 | chr16:48365467 del T | 5'Flank (DEL) | VAF 19/142 reads (13%) | called by mutect2, pindel, varscan2
- SNRPB | c.-22C>T | 5'UTR (SNP) | VAF 41/347 reads (12%) | called by muse, mutect2, varscan2
- SNX29P1 | n.860C>A | RNA (SNP) | VAF 43/217 reads (20%) | called by muse, mutect2, varscan2
- STXBP2 | c.903-19C>T | Intron (SNP) | VAF 73/194 reads (38%) | catalogued as rs762417426; called by muse, mutect2, varscan2
- THRB | c.284-12837G>C | Intron (SNP) | VAF 15/77 reads (19%) | catalogued as rs760312808; called by muse, mutect2, varscan2
- TK2 | c.64-4848G>A | Intron (SNP) | VAF 36/300 reads (12%) | called by muse, mutect2, varscan2
- UBR4 | c.15009-138A>T | Intron (SNP) | VAF 22/140 reads (16%) | called by mutect2, varscan2
- USH2A | c.7451+18T>C | Intron (SNP) | VAF 67/406 reads (17%) | called by muse, mutect2, varscan2
- WASF4P | n.277G>C | RNA (SNP) | VAF 62/190 reads (33%) | called by muse, mutect2, varscan2
- ZNF841 | c.-78+7869G>A | Intron (SNP) | VAF 58/269 reads (22%) | called by muse, mutect2, varscan2
